Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A103, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A103-01A (Primary Tumor).

[page 1 of 2]
100-0-3
Adenocarcinoma, endometrioid, NOS 8380/3
Site Code: Endometrium C54.1 1/17/11 lu

DIAGNOSIS:

A. Uterus, hysterectomy: FIGO grade 1 (of 3) endometrial adenocarcinoma, endometrioid type, forming a mass (2.2 x 1.9 x 0.5 cm) located on the posterior uterine wall. The tumor invades 0.4 cm into the myometrium (total myometrial thickness, 1.4 cm). The tumor does not involve the endocervix. The cervix is unremarkable. Lymphovascular space invasion is not identified. The margins are negative for tumor. [AJCC pT1bNXMX]

B. Ovary, right, oophorectomy: Unremarkable ovary. No fallopian tube grossly or microscopically identified. There is a 1.0 x 0.7 x 0.6 cm paratubal cyst.

C. Ovary and fallopian tube, left, salpingo-oophorectomy: Unremarkable ovary and fallopian tube.

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 45.0 gram uterus with unremarkable cervix. The uterine serosa is smooth. There is a 2.2 x 1.9 x 0.5 cm mass in the posterior wall and a 0.5 x 0.3 x 0.3 cm mass in the right anterior wall of the endometrial cavity. The myometrial thickness is 1.4 cm. There are no leiomyomas in the myometrium. Representative sections are submitted.

[page 2 of 2]
B. Received fresh labeled "right fallopian tube and ovary" is a 2.0 x 1.4 x 0.9 cm ovary with a 1.0 x 0.7 x 0.6 cm cyst in the adjacent soft tissue. The right fallopian tube is not identified. The ovary has a smooth outer surface and a solid cut surface. Representative sections are submitted.

C. Received fresh labeled "left fallopian tube and ovary" is a 2.2 x 1.4 x 0.7 cm ovary with a 4.4 x 0.5 cm attached fallopian tube. The ovary has a smooth outer surface and a solid cut surface. There are hemorrhagic adhesions on the surface of the fallopian tube and ovary which are grossly suspicious for endometriosis. Representative sections are submitted.

BLOCK SUMMARY:

Part A: Uterus

- 1 Endometrium-Post wall 1
- 2 Endometrium-Post wall 2
- 3 Endometrium-Post wall 3
- 4 Endometrium-Post wall 4
- 5 Endometrium-Rt Ant wall
- 6 Lower uterine segment
- 7 Cervix

Part B: Right Ovary and fallopian tube

- 1 Adjacent to rt ovary cyst
- 2 Right ovary

Part C: Left Ovary and fallopian tube

- 1 Left tube
- 2 Left ovary
- 3 Surface left ovary

HPAIA Discrepancy		☒

Source: NCI Genomic Data Commons file ac23897d-a625-40b4-847d-393d4b5a9554 (TCGA-D1-A103.AE2FAD3D-FA6A-4648-90A5-2D2C442796AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).